Somatic mutation profile of tumor specimen 0DRMOJ from CCDI case PBCGTV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,650 days).
Specimen 0DRMOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b81375df-c411-450d-98ea-a8164f5211b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRMOM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d818362e-d12b-4ccb-8349-16f3378462f7

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Intron 3, Nonsense Mutation 3, In Frame Ins 2, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJA5 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 203/674 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs387906613, CM104883, COSV99605540; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BPIFB1 | c.393C>A p.F131L | Missense Mutation (SNP) | VAF 197/647 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53606661; called by muse, mutect2, varscan2
- BPIFC | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 253/910 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs113455565, COSV55910993; called by muse, mutect2, varscan2
- CATSPERB | c.3208G>T p.G1070* | Nonsense Mutation (SNP) | VAF 114/531 reads (21%) | catalogued as rs1465184543, COSV99831250; called by mutect2, varscan2
- COL12A1 | c.4780C>T p.R1594C | Missense Mutation (SNP) | VAF 36/922 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1306651193, COSV59391478; called by muse, mutect2
- KLK15 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 26/683 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1041779437, COSV100032910; called by muse, mutect2
- OPRL1 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 255/554 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745570699, COSV100402206; called by muse, mutect2, varscan2
- OR4C6 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 203/642 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.317); catalogued as rs367948844, COSV58603115; called by muse, mutect2, varscan2
- POTEJ | c.407A>T p.K136M | Missense Mutation (SNP) | VAF 66/431 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as rs527899139; called by muse, mutect2, varscan2
- PRR30 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 184/1009 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs767357441, COSV53207464; called by muse, mutect2, varscan2
- TRIM9 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 180/764 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53618618; called by muse, mutect2, varscan2
- ZNF324 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 147/470 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as rs756367139, COSV52179633; called by muse, mutect2, varscan2
- ATXN7L3 | c.628G>A p.G210R (on ENST00000389384 / NM_001382309.1; = p.G217R on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/472 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- GZMB | c.731T>G p.M244R | Missense Mutation (SNP) | VAF 96/504 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IL32 | c.272A>C p.E91A (on ENST00000396890 / NM_001308078.4; = p.E45A on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/394 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PRR14L | c.233A>T p.E78V | Missense Mutation (SNP) | VAF 161/545 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PXDN | c.2455_2460dup p.M819_Q820dup | In Frame Ins (INS) | VAF 134/652 reads (21%) | called by mutect2, varscan2
- RASGEF1B | c.1389_1391dup p.S464dup | In Frame Ins (INS) | VAF 107/469 reads (23%) | called by mutect2, pindel, varscan2
- SGPP2 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 191/667 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHOC1 | c.3087G>A p.W1029* | Nonsense Mutation (SNP) | VAF 107/604 reads (18%) | called by muse, mutect2, varscan2
- SPANXN4 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- THBS2 | c.1518C>A p.C506* | Nonsense Mutation (SNP) | VAF 157/671 reads (23%) | called by muse, mutect2, varscan2
- NIT1 | c.375C>A p.S125= | Silent (SNP) | VAF 105/345 reads (30%) | called by muse, mutect2, varscan2
- ODF2L | c.339A>G p.L113= | Silent (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- OR7A17 | c.612G>T p.G204= | Silent (SNP) | VAF 105/351 reads (30%) | catalogued as rs755615843; called by muse, mutect2, varscan2
- PAPPA | c.3573C>T p.S1191= | Silent (SNP) | VAF 190/813 reads (23%) | called by muse, mutect2, varscan2
- SALL1 | c.3327G>A p.P1109= | Silent (SNP) | VAF 203/471 reads (43%) | catalogued as rs375357921; called by muse, mutect2, varscan2
- SDK1 | c.3804G>A p.R1268= | Silent (SNP) | VAF 177/192 reads (92%) | called by muse, mutect2, varscan2
- SLFN12 | c.105A>G p.K35= | Silent (SNP) | VAF 28/942 reads (3%) | called by muse, mutect2
- LINC02465 | n.459+295A>T | Intron (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- LRP5 | c.1801+668T>C | Intron (SNP) | VAF 84/293 reads (29%) | called by muse, mutect2, varscan2
- NCSTN | c.1795-37C>T | Intron (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- SCGB1D4 | c.-58T>C | 5'UTR (SNP) | VAF 11/176 reads (6%) | called by muse, mutect2
- TMEM25 | c.*906G>A | 3'UTR (SNP) | VAF 132/295 reads (45%) | called by muse, mutect2, varscan2
- WDR83 | c.*32C>T | 3'UTR (SNP) | VAF 109/371 reads (29%) | catalogued as rs756634410; called by muse, mutect2, varscan2
